FM case AD11133 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Basal Cell Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/dc24c698-e7cd-461e-a7bd-cf98ab7ca870

Female, 49.1 years: Basal cell carcinoma, NOS (ICD-O-3 8090/3) of the skin; primary biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
